Somatic mutation profile of tumor specimen MMRF_1694_1_BM_CD138pos (aliquot MMRF_1694_1_BM_CD138pos_T1_KBS5U_L04795) from MMRF case MMRF_1694, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,422 days).
Specimen MMRF_1694_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc1bb80a-920b-4198-91d4-ed10340e5a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1694_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1694_1_PB_Whole_C3_KBS5U_L04807; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11be7392-bc44-4c19-8dd3-2f677bcf7823

The open-access MAF lists 92 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 20, Silent 13, Intron 9, 5'UTR 6, RNA 2, 5'Flank 2, 3'Flank 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO15A | c.4198G>A p.V1400M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749136456, CM105323; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5519G>A p.R1840H | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs563366603, COSV51851942; called by muse, mutect2, varscan2
- ATR | c.2941G>A p.V981I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.314); catalogued as rs369913351; called by muse, mutect2, varscan2
- CD274 | c.720C>A p.H240Q | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV67501738; called by muse, mutect2, varscan2
- CSMD3 | c.1208A>T p.N403I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.177); catalogued as COSV52241389; called by muse, mutect2, varscan2
- FRYL | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1443397225; called by muse, mutect2, varscan2
- FZD10 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 62/69 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1185084864, COSV57472150, COSV57472925; called by muse, mutect2, varscan2
- IHH | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs749777278; called by muse, mutect2, varscan2
- LAMB4 | c.4186G>A p.G1396S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV99225146; called by muse, mutect2, varscan2
- MYO1F | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs201138222, COSV57796026; called by muse, mutect2, varscan2
- NOL4 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774936266, COSV52357422, COSV99307946; called by muse, mutect2, varscan2
- PLOD2 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.338); catalogued as rs370188153; called by muse, mutect2, varscan2
- SLC39A12 | c.326_328del p.E109del | In Frame Del (DEL) | VAF 36/63 reads (57%) | catalogued as rs782682656; called by pindel, varscan2
- ACE | c.3313C>G p.P1105A | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- AUTS2 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC114 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP112 | c.2066A>C p.D689A | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CLCN6 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYLC2 | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ERBB4 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEPHL1 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- HID1 | c.2023A>T p.S675C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- IGHV1-69D | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2
- MED12 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NONO | c.1204_1208dup p.A404Pfs*18 | Frame Shift Ins (INS) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- NPAT | c.1455T>G p.I485M | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PCDH7 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PLEKHA2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PSMA1 | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PTPRJ | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- QSOX2 | c.1079T>C p.L360S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2
- RALGAPB | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RBM42 | c.899T>A p.L300H | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- RRBP1 | c.2880T>G p.I960M (on ENST00000377813 / NM_001365613.2; = p.I527M on NM_004587.3) | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SAMD9 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TCERG1 | c.2876A>T p.E959V | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- TMEM266 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- UCKL1 | c.924G>A p.R308= | Splice Region (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- ZNF292 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- DSG1 | c.1590T>C p.S530= | Silent (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- DST | c.16218C>T p.S5406= (on ENST00000361203 / NM_001374722.1; = p.S2994= on NM_015548.5) | Silent (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- HDGFL1 | c.219C>T p.R73= | Silent (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- HNRNPDL | c.294C>A p.S98= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as COSV55022324; called by muse, mutect2
- HYOU1 | c.816C>T p.G272= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.36A>G p.L12= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as rs762981285; called by muse, mutect2, varscan2
- IGLV4-60 | c.231C>T p.Y77= | Silent (SNP) | VAF 81/86 reads (94%) | catalogued as rs567096325, COSV66503515; called by muse, mutect2, varscan2
- IQGAP2 | c.1278A>G p.Q426= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- NEB | c.1347C>T p.V449= | Silent (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- NFKBIB | c.834C>T p.L278= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs750595727; called by muse, mutect2, varscan2
- STEAP4 | c.1122C>T p.V374= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- STYK1 | c.81T>A p.I27= | Silent (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- TCF25 | c.1866C>A p.T622= | Silent (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- ACTB | c.-27-121G>A | Intron (SNP) | VAF 66/129 reads (51%) | catalogued as rs533676634, COSV59317189; called by muse, mutect2, varscan2
- ALG3 | c.605+50T>A | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- C9orf62 | n.58T>C | RNA (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- CAPN8 | c.1136-999G>A | Intron (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- CCDC178 | c.*186G>T | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- CCDC69 | c.-117C>T | 5'UTR (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2
- CD74 | c.*425T>C | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- CNNM4 | c.*744G>A | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- CSPG5 | c.*298A>G | 3'UTR (SNP) | VAF 98/212 reads (46%) | called by muse, mutect2, varscan2
- DESI1 | c.*1910C>A | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- E2F3 | c.*1461G>A | 3'UTR (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- ESPNP | n.1458G>A | RNA (SNP) | VAF 3/33 reads (9%) | catalogued as rs1226900715; called by muse, mutect2
- F2R | c.*494A>G | 3'UTR (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- FDX1 | c.*1318T>A | 3'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- GLRA3 | c.*2358C>T | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- H2BC8 | c.*68T>G | 3'UTR (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- HMGB4 | c.-1194C>T | 5'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- INSIG2 | c.*1732G>C | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- IPO5 | c.*296C>A | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- KITLG | chr12:88580700 G>T | 5'Flank (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- LCT | c.986+14G>A | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2
- LOXHD1 | c.-6G>C | 5'UTR (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- NPY2R | c.*29G>A | 3'UTR (SNP) | VAF 109/219 reads (50%) | called by muse, mutect2, varscan2
- NREP | c.*431A>G | 3'UTR (SNP) | VAF 133/260 reads (51%) | catalogued as rs759845984; called by muse, mutect2, varscan2
- PEG10 | c.*797A>T | 3'UTR (SNP) | VAF 206/452 reads (46%) | called by muse, mutect2, varscan2
- PRDM13 | c.*588A>C | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- PROS1 | c.-27C>T | 5'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PTP4A1 | c.*1527G>A | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- PYGO1 | c.49+895G>C | Intron (SNP) | VAF 58/150 reads (39%) | catalogued as rs202218683; called by muse, mutect2, varscan2
- RANBP1 | c.505+248C>T | Intron (SNP) | VAF 36/44 reads (82%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.-29G>C | 5'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, varscan2
- SLC29A2 | c.*192T>C | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- SYNPO2L | c.257+13C>G | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34578956 C>G | 5'Flank (SNP) | VAF 34/226 reads (15%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2074G>A | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TWIST2 | c.-7G>A | 5'UTR (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- UBE2I | c.*1534C>T | 3'UTR (SNP) | VAF 62/124 reads (50%) | catalogued as rs1322446131; called by muse, mutect2, varscan2
- USP17L30 | chr4:9369029 T>C | 3'Flank (SNP) | VAF 17/69 reads (25%) | catalogued as rs1200951437; called by mutect2, varscan2
- WDR45 | c.516+26G>A | Intron (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- ZFHX2 | c.*568C>T | 3'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
